Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N5, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N5-01A (Primary Tumor).

[page 1 of 2]
ICD-3

Adenocarcinoma, mucinous NOS 8480/3
Site ^{OGSE} Gastric antrum C16.1
Path Lesser curvature of stomach C16.5
7/23/28/14

(Specimen Collected:

Comment for
HISTOPATHOLOGY REPORT

HISTOLOGY

REQUEST DETAILS

Gastric cancer of gastric remnant. (Previous poly... gastrectomy).
Completion gastrectomy for gastric cancer (previous

Frozen section diagnosis: No evidence of carcinoma.

MACROSCOPIC DESCRIPTION

1. Specimen labelled lymph node. A soft tissue fragment up to 6mm. All tissues for Frozen Section and processed in Block 1.1.
2. Specimen labelled stomach. A portion of stomach 140 x 100 x 50mm. A portion of adipose tissue is attached to what is presumed to be the lesser curvature, adjacent to the insertion of the distal part of the oesophagus. Free floating nodules of tumour are found in the lumen of the stomach. The oesophageal margin is not stapled. Approximately 60mm from the oesophageal margin a stapled resection margin is seen, also adjacent to the adipose tissue. A further 35mm from this point, a second stapled resection is seen. Adjacent to the oesophago-gastric junction on the lesser curvature of the stomach, is a tumour mass measuring 60 x 45mm. The tumour is 60mm from the first stapled margin and 45mm from the second stapled margin. The tumour is approximately 7mm from the oesophageal resection margin. Margins marked with black ink. On cross-section through the tumour the tumour is seen to extend through the stomach wall into adjacent adipose tissue. Minimal adipose tissue is present on the presumed greater curvature. Blocks selected 2.1 oesophageal margin, 2.2 first gastric margin, 2.3 second gastric margin, 2.4-2.6 composite section of tumour, 2.7 random stomach, 2.8-2.9 lesser curvature nodes, 2.10 greater curvature nodes.
3. Specimen labelled specimen donuts. Two donuts are received. Representative sample processed in one block.

MICROSCOPIC DESCRIPTION

1. One lymph node is identified, free of tumour.
2. The tumour comprises pools and lakes of abundant mucin containing strips of columnar epithelium with only moderate nuclear atypia and basal nuclei. Numerous foamy macrophages are present and some cells with a signet ring appearance; however these are not prominent. There is no lymphovascular or perineural invasion. The tumour extends through the muscularis propria and into serosal fat but appears clear of the radial resection margin. The tumour is clear of the resection margin. In the surrounding stomach, there is a mild-to-moderate infiltrate of chronic inflammatory cells in the lamina propria with scattered neutrophils. Numerous helicobacter organisms are present. No intestinal metaplasia or dysplasia are seen in the adjacent mucosa. Four of seventeen lesser curvature lymph nodes contain tumour. In addition to this, three extranodal deposits of tumour are identified. Four greater curvature nodes are identified, free of tumour.
3. The donuts are unremarkable.

DIAGNOSIS

1. Lymph node: One lymph node, free of tumour.
2. Completion gastrectomy: Adenocarcinoma, mucinous variant, with extension through muscle wall into serosal fat. Four of twenty one lymph nodes contain tumour (pT2N1Mx). Extranodal serosal tumour deposits are noted. Margins are clear.

[page 2 of 2]
3. Donuts: Unremarkable.

Source: NCI Genomic Data Commons file 83beb350-6e7b-42ee-ae06-dc87f05b5e1c (TCGA-RD-A8N5.33A55F32-A6AB-4470-A393-8040A6DF8C83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).